Surgical pathology report (de-identified scan), TCGA case TCGA-02-2483, project TCGA-GBM (Glioblastoma Multiforme), tissue source site MD Anderson Cancer Center, specimen TCGA-02-2483-01A (Primary Tumor).

TCGA-02-2483

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) BRAIN, "RIGHT TEMPORAL TUMOR"

DIFFUSE ASTROCYTOMA, WHO GRADE 4, OR GLIOBLASTOMA. (SEE COMMENT).

(B) BRAIN, "RIGHT TEMPORAL TUMOR"

DIFFUSE ASTROCYTOMA, WHO GRADE 4, OR GLIOBLASTOMA. (SEE COMMENT).

GROSS DESCRIPTION

(A) "RIGHT TEMPORAL TUMOR" - Consists of a fragment of cortex and white matter containing blood clot and tumor. In some areas there is gray-white junction demarcation, however, the majority of the specimen is infiltrated by neoplasm. Representative section labeled A1 for frozen section and two touch preps are made. Representative sections are labeled A2-A8 for permanent section, and the remainder is submitted to the Brain Tumor Center Tissue Bank.

DX: A1 (TOUCH PREPS AND FROZEN SECTION USED TOGETHER TO FORMULATE THE DIAGNOSIS):
HIGH GRADE GLIOMA. PATIENT HAS HAD PRIOR SURGERY SHOWING ANAPLASTIC ASTROCYTOMA

(B) "RIGHT TEMPORAL TUMOR" - Consists of multiple fragments of hemorrhagic soft tumor together measuring 3.0 x 2.5 x 0.7 cm. Labeled B1-B3. Jar 0.

COMMENT

The patient has had a prior biopsy that showed anaplastic astrocytoma

CLINICAL HISTORY

None given.

SNOMED CODES

T-A2000, M-94403

Source: NCI Genomic Data Commons file 46053d1b-0f79-4fe9-9c11-73264357e17e (TCGA-02-2483.E73F6BA1-564C-4FEA-B088-F2357FF49EE7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).